TCGA case TCGA-G4-6625 — Colon Adenocarcinoma (TCGA-COAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon; Tissue source site: Roswell Park. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5eed7e8a-c219-4497-a99f-bfc48faca4d8

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 77 years; Vital status: Alive.

Diagnoses (4)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C18.7; Tissue or organ of origin: Sigmoid colon; Site of resection or biopsy: Sigmoid colon; Classification of tumor: primary; Age at diagnosis: 77.1 years (28,163 days); Year of diagnosis: 2004; AJCC staging edition: 5th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 2,792 days (7.6 years).
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 18; Lymphatic invasion present: No; Non nodal tumor deposits: No; Perineural invasion present: No; Vascular invasion present: No.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Classification of tumor: Prior primary.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; Tissue or organ of origin: Breast, NOS; Laterality: Right; Classification of tumor: Prior primary.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment anatomic sites: Body, total.
   Recorded as not given: Radiation Therapy, NOS.
4. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 84.1 years (30,727 days); Days to diagnosis: 2,564 days (7.0 years); Prior treatment: Yes.
   Treatment given: Treatment type: Radiation Therapy, NOS.
   Recorded as not given: Pharmaceutical Therapy, NOS; Surgery, NOS.

Follow-up (3 entries)
- Day 2,564 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 2,564 days (7.0 years).
- Days to follow up: 2,673 days (7.3 years); Disease response: With Tumor.
- Days to follow up: 2,792 days (7.6 years); Disease response: Tumor Free.

Molecular and laboratory tests
- CEA: 5.5 ng/mL.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 65.5 kg; Height: 149 cm; BMI: 29.5.
- Timepoint category: Initial Diagnosis; Comorbidities: Colon Polyps; Risk factors: Colon Polyps.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-G4-6625-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.2; Intermediate dimension: 0.9; Shortest dimension: 0.4.
  Slide TCGA-G4-6625-01A-01-BS1: Section location: Top; Percent tumor cells: 55; Percent tumor nuclei: 60; Percent normal cells: 10; Percent necrosis: 10; Percent stromal cells: 25.
- Sample TCGA-G4-6625-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-G4-6625-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.2; Intermediate dimension: 0.9; Shortest dimension: 0.4.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Height cm at diagnosis: 149 cm; Lymph nodes examined: Yes; CEA level pretreatment: 5.5; Lymphovascular invasion indicator: No; KRAS gene analysis indicator: No; BRAF gene analysis indicator: No; History colon polyps: No; Colon polyps at procurement indicator: Yes; Mismatch rep proteins tested by IHC: No.
- Follow-up form: Tumor status: Tumor free; New tumor event diagnosis indicator: Yes.
- Follow-up form, New tumor event: New tumor event surgery: No; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: No.
- Other malignancy form 1: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Breast; Other malignancy histological type: Invasive Ductal Carcinoma.
- Other malignancy form 1, Surgery: Days from index date to other malignancy surgery: -10632.
- Other malignancy form 1, Drug treatment: Pharmaceutical therapy extent: Systemic.
- Other malignancy form 2: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Skin; Other malignancy histological type: Melanoma.

GDC annotations on this case (curator notes; quoted as recorded):
- History of unacceptable prior treatment related to a prior/other malignancy: Prior malignancy R breast treated with chemotherapy.
- Prior malignancy: Prior malignancy melanoma. No systemic chemotherapy or radiation. Prior malignancy R breast treated with chemotherapy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 2,792 days; disease-specific survival: no event (censored), 2,792 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 2,564 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-G4-6625-01): tumor purity 0.34, ploidy 2.92, whole-genome doublings 1 (call status: legacy_call).
